Gene-level copy-number profile of tumor specimen C3N-01017-04 from CPTAC case C3N-01017, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,756 days).
Specimen C3N-01017-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c00c4aa-c77a-4579-9328-9a511921f133.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01017-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/b8ba4bad-411c-4417-aea7-83e332aa741b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 330; copy number 1: 17,284; copy number 2: 34,359; copy number 3: 4,630; copy number 4: 1,804; copy number 5: 424; copy number 15: 47; copy number 19: 37.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:35,118,071–35,148,610, 1 gene: TCP11.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 508 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,083,499–170,305,977, 31 genes, copy number 5: MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA.
- chr3:172,425,850–173,336,965, 17 genes, copy number 5: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:178,272,932–178,844,429, 2 genes, copy number 5 (within-gene range 4–5): KCNMB2, AC117457.1.
- chr3:178,526,505–179,267,002, 8 genes, copy number 5 (within-gene range 4–5): KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1.
- chr3:180,413,008–184,740,104, 113 genes, copy number 5 (broad region; genes not listed).
- chr3:184,741,937–184,743,284, 2 genes, copy number 5: AC107294.3, AC107294.1.
- chr3:186,105,668–197,299,330, 239 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:8,572,047–14,532,128, 84 genes, copy number 15–19 (broad region; genes not listed).
- chr19:40,090,754–40,348,527, 12 genes, copy number 5 (within-gene range 3–5): AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 14,748. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
